Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16R, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16R-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

A. Abdomen, panniculectomy: Skin and subcutaneous tissue, 1590.0 grams, identified grossly. Gross examination only.

B. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: Invasive endometrial adenocarcinoma, endometrioid type, FIGO grade I (of III) is identified forming a mass (10.7 x 7.8 x 2.1 cm) circumferentially involving the endometrial cavity. The tumor invades 0.6 cm into the myometrium (total myometrial thickness, 3.2 cm) but does not involve the endocervix. Lymphovascular space invasion is not identified. All surgical resection margins are negative for tumor. The bilateral ovaries and fallopian tubes are not involved and are histologically unremarkable. Selected slides seen with

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple (24) right pelvic lymph nodes are negative for tumor.

D. Lymph nodes, left pelvic, lymphadenectomy: Multiple (22) left pelvic lymph nodes are negative for tumor.

E. Lymph nodes, additional right pelvic, lymphadenectomy: Multiple (3) right pelvic lymph nodes are negative for tumor.

Photograph taken.

[page 2 of 4]
With available surgical material [AJCC pT1aN0] (7th edition, 2010).

PRELIMINARY FROZEN SECTION CONSULTATION:

B. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: Invasive endometrial adenocarcinoma, endometrioid type, invading 0.6 cm into the myometrium (total myometrium thickness of 3.2 cm). Hold over to evaluate further on permanent sections.

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple (24) right pelvic lymph nodes are negative for tumor.

D. Lymph nodes, left pelvic, lymphadenectomy: Multiple (22) left pelvic lymph nodes are negative for tumor.

E. Lymph nodes, additional right pelvic, lymphadenectomy: Multiple (3) right pelvic lymph nodes are negative for tumor.

GROSS DESCRIPTION:

A. Received fresh labeled "abdominal pannus" is a 1590.0 gram portion of skin and subcutaneous tissue without umbilicus. No

lesions identified. Gross examination only.

B. Received fresh labeled "uterus, right and left fallopian tubes and ovaries" is a 460.0 gram uterus with attached bilateral tubes and ovaries. The uterine serosa is smooth. There is a 10.7 x 7.8 x

2.1 cm exophytic mass filling the entire endometrial cavity. The myometrial thickness is 3.2 cm. There are no leiomyomata. There is

a 3.0 x 2.4 x 1.5 cm right ovary with a smooth outer surface and a cystic and solid cut surface with a 7.5 x 0.6 cm right fallopian

[page 3 of 4]
tube which is unremarkable. There is a 3.4 x 2.5 x 1.2 cm left

ovary with a smooth outer surface and a cystic and solid cut surface

with a 7.4 x 0.5 cm left fallopian tube which is unremarkable.

Photograph taken. Representative sections are submitted.

C. Received fresh labeled "right pelvic lymph nodes" is a 9.5 x 7.0

x 2.4 cm aggregate of adipose and lymphatic tissue. Lymph nodes

submitted.

D. Received fresh labeled "left pelvic lymph nodes" is a 7.8 x 4.7

x 1.6 cm aggregate of adipose and lymphatic tissue. Lymph nodes

submitted.

E. Received fresh labeled "additional right pelvic lymph nodes" is

a 3.0 x 1.6 x 0.4 cm aggregate of adipose and lymphatic tissue.

Lymph nodes submitted.

BLOCK SUMMARY:

Part A: Abdominal Pannus

Part B: Uterus, tubes, ovaries

- 1 Endometrial mass
- 2 Cervix
- 3 Lower uterine segment
- 4 Left tube
- 5 Left ovary
- 6 Right tube
- 7 Right ovary
- 8 Endometrial mass-2
- 9 Endometrial mass-3
- 10 Endometrial mass-4
- 11 Endometrial mass-5

Part C: Right Pelvic Lymph Nodes

- 1 Rt pelvic LN (C1)2
- 2 Rt pelvic LN (C2)1
- 3 Rt pelvic LN (C3)2
- 4 Rt pelvic LN (C4)4

[page 4 of 4]
5 Rt pelvic LN (C5)1of2
6 Rt pelvic LN (C5)2of2
7 Rt pelvic LN (C6)2
8 Rt pelvic LN (C7)5
9 Rt pelvic LN (C8)3
10 Rt pelvic LN (C9)1
11 Rt pelvic LN (C10)1of2
12 Rt pelvic LN (C10)2of2

Part D: Left Pelvic Lymph Nodes

1 Lt pelvic LN (D1)3
2 Lt pelvic LN (D2)5
3 Lt pelvic LN (D3)3
4 Lt pelvic LN (D4)5
5 Lt pelvic LN (D5)2
6 Lt pelvic LN (D6)1
7 Lt pelvic LN (D7)1
8 Lt pelvic LN (D8)1
9 Lt pelvic LN (D9)1of2
10 Lt pelvic LN (D9)2of2

Part E: Additional right pelvic lymph nodes

1 Rt pelvic LNs 3 (E1)

Source: NCI Genomic Data Commons file cae2519e-5e81-46bf-b9f6-5e7c70f6a81b (TCGA-D1-A16R.D9641375-D204-4469-989A-ED08DDE66408.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).